Gene-level copy-number profile of tumor specimen TCGA-QK-A6IH-01A from TCGA case TCGA-QK-A6IH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Gum, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 65.5 years (23,936 days).
Specimen TCGA-QK-A6IH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.0fee7509-74d1-470b-94f2-f111a6fbdc1e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QK-A6IH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/edf44c49-745c-45f6-9e62-d29b06ec15ff

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 354; copy number 2: 14,870; copy number 3: 7,662; copy number 4: 32,842; copy number 5: 803; copy number 6: 817; copy number 7: 1,239; copy number 8: 1,034; copy number 9: 63; copy number 10: 8; copy number 11: 6; copy number 12: 5; copy number 13: 8; copy number 14: 30; copy number 19: 24; copy number 21: 6; copy number 24: 17; copy number 41: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QK-A6IH-01A-11D-A31K-01): tumor purity 0.76, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr9:28,598,668–28,888,955, 3 genes: KCTD10P1, MIR876, MIR873.
- chr10:34,109,560–34,815,325, 1 gene (within-gene range 0–2): PARD3.
- chr10:34,488,583–34,676,041, 3 genes: ELOBP4, RPL37P18, RPS12P16.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 183 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,638,405–86,496,996, 14 genes, copy number 10–19: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070.
- chr4:145,335,263–146,200,000, 20 genes, copy number 9: LINC02266, RTN3P1, AC079228.1, AC093796.1, NMNAT1P4, SMAD1, SMAD1-AS2, SMAD1-AS1, MMAA, NCOA4P3, AC093864.1, C4orf51, ZNF827, AC104791.2, AC104791.1, Y_RNA, AC108206.1, LINC01095, LSM6, AC097372.2.
- chr4:148,078,762–151,015,727, 29 genes, copy number 9: NR3C2, AC069272.1, AC002460.2, ASS1P8, RNA5SP166, AC108935.1, ATP5MGP4, AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430, LINC02355, IQCM, AC108168.1, AC093893.1, AKIRIN2P1, RNA5SP167, RNU6-1230P, AC105343.1, AC105343.2, DCLK2, RNU7-194P, LRBA, AC092612.1, AC110813.1, MAB21L2, ZBTB8OSP1, RNA5SP168.
- chr4:151,904,932–152,680,012, 23 genes, copy number 14 (within-gene range 4–14): AC097375.2, AC097375.1, AC097375.4, AC097375.3, RNA5SP169, AC097375.5, LINC02273, AC079340.3, AC079340.1, AC079340.2, RN7SL446P, AC080078.1, AC080078.2, FBXW7, FBXW7-AS1, AC023424.2, MIR3140, MIR4453HG, MIR4453, RPS3AP18, AC023424.1, TMEM154, AC106882.1.
- chr11:68,612,899–71,252,577, 64 genes, copy number 11–41 (within-gene range 2–41) (broad region; genes not listed).
- chr12:2,954,240–3,072,145, 4 genes, copy number 12: RNU6-1315P, TEAD4, AC125807.2, AC125807.1.
- chr12:3,124,777–3,125,063, 1 gene, copy number 12: Metazoa_SRP.
- chr12:31,280,422–31,853,407, 28 genes, copy number 9–21: AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3.

Autosomal genes at a single copy (total copy number 1): 354. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
